Somatic mutation profile of tumor specimen MMRF_2373_1_BM_CD138pos (aliquot MMRF_2373_1_BM_CD138pos_T2_KHS5U_K14032) from MMRF case MMRF_2373, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Dead; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 67.1 years (24,525 days).
Specimen MMRF_2373_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ed79bbb1-4625-4ebb-84c2-e65a6d989ede.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2373_1_PB_CD3pos (Blood Derived Normal), aliquot MMRF_2373_1_PB_CD3pos_C1_KHS5U_K14033; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6caa7ba4-cf3f-4c01-92bc-13a20d903f9e

The open-access MAF lists 110 somatic variants for this specimen: 43 protein-altering or splice-affecting, 10 silent, 57 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 39, 3'UTR 32, Intron 15, Silent 10, 3'Flank 3, 5'UTR 3, 5'Flank 3, Frame Shift Ins 1, RNA 1, Frame Shift Del 1, Splice Site 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.481G>A p.A161T | Missense Mutation (SNP) | VAF 46/47 reads (98%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs193920817, COSV52660939, COSV52789715, COSV53470581; ClinVar: conflicting interpretations of pathogenicity / uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- ADAMTS10 | c.345G>C p.Q115H | Missense Mutation (SNP) | VAF 19/139 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.91); catalogued as COSV54354947; called by muse, mutect2, varscan2
- AFAP1L1 | c.832C>T p.R278W | Missense Mutation (SNP) | VAF 39/74 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs368271604; called by muse, mutect2, varscan2
- CAMSAP1 | c.2219C>T p.S740L | Missense Mutation (SNP) | VAF 158/353 reads (45%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.582); catalogued as rs769853731; called by muse, mutect2, varscan2
- CNTLN | c.3652G>A p.E1218K | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.385); catalogued as rs1173032868; called by muse, mutect2, varscan2
- CWC27 | c.1160C>T p.A387V | Missense Mutation (SNP) | VAF 73/144 reads (51%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.941); catalogued as rs914036534; called by muse, mutect2, varscan2
- DOP1A | c.3373G>C p.E1125Q | Missense Mutation (SNP) | VAF 10/214 reads (5%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.308); catalogued as COSV99381938; called by muse, mutect2
- DUSP19 | c.280C>T p.H94Y | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61193526; called by muse, mutect2
- GPRC5B | c.853A>C p.I285L | Missense Mutation (SNP) | VAF 63/169 reads (37%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV56024927; called by muse, mutect2, varscan2
- KCNS1 | c.1156G>T p.G386C | Missense Mutation (SNP) | VAF 61/64 reads (95%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1262560671, COSV100066944; called by muse, mutect2, varscan2
- KCTD5 | c.373G>A p.E125K | Missense Mutation (SNP) | VAF 21/40 reads (53%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.964); catalogued as COSV57064894; called by muse, mutect2, varscan2
- KIAA1210 | c.4969C>T p.Q1657* | Nonsense Mutation (SNP) | VAF 3/48 reads (6%) | catalogued as COSV68179718; called by muse, mutect2
- LRRC52 | c.773C>T p.A258V | Missense Mutation (SNP) | VAF 50/116 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.826); catalogued as rs769884053, COSV54233994; called by muse, mutect2, varscan2
- MFN1 | c.961G>A p.E321K | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54941250, COSV99764315; called by muse, mutect2, varscan2
- OR4A47 | c.790C>T p.P264S | Missense Mutation (SNP) | VAF 63/93 reads (68%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.015); catalogued as rs1468528217; called by muse, mutect2, varscan2
- SLC1A7 | c.595G>A p.A199T | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT tolerated (0.76); PolyPhen benign (0.041); catalogued as rs149217403, COSV65194231; called by muse, mutect2, varscan2
- SLITRK3 | c.2177C>A p.T726N | Missense Mutation (SNP) | VAF 34/153 reads (22%) | SIFT tolerated (0.58); PolyPhen benign (0.007); catalogued as rs781327881, COSV53854229; called by muse, mutect2, varscan2
- TMSB4X | c.-17+1G>A | Splice Site (SNP) | VAF 80/82 reads (98%) | catalogued as COSV66081196, COSV66081636; called by muse, varscan2
- TNK2 | c.664G>A p.G222S | Missense Mutation (SNP) | VAF 67/142 reads (47%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.841); catalogued as rs1202675063; called by muse, mutect2, varscan2
- TSHZ1 | c.372C>A p.F124L (on ENST00000580243 / NM_001308210.2; = p.F79L on NM_005786.6) | Missense Mutation (SNP) | VAF 10/123 reads (8%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1452836402; called by muse, mutect2
- URB1 | c.1516C>T p.P506S | Missense Mutation (SNP) | VAF 4/66 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs867899296, COSV101236615; called by muse, mutect2
- ZZEF1 | c.1120C>T p.H374Y | Missense Mutation (SNP) | VAF 121/285 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV67556889; called by muse, mutect2, varscan2
- ADGRL1 | c.3947G>A p.G1316D (on ENST00000340736 / NM_001008701.3; = p.G1311D on NM_014921.5) | Missense Mutation (SNP) | VAF 46/108 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.882); called by muse, varscan2
- CACNA2D4 | c.1039C>T p.L347F | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CD19 | c.1210G>C p.E404Q | Missense Mutation (SNP) | VAF 9/102 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.662); called by muse, mutect2
- DPEP3 | c.854C>G p.P285R | Missense Mutation (SNP) | VAF 57/103 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- FAR2 | c.865G>A p.G289R | Missense Mutation (SNP) | VAF 43/95 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); called by muse, mutect2, varscan2
- FRMPD4 | c.544G>C p.E182Q | Missense Mutation (SNP) | VAF 4/45 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- HCN4 | c.3260C>G p.S1087C | Missense Mutation (SNP) | VAF 32/102 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.57); called by muse, mutect2, varscan2
- LAMA1 | c.6246del p.F2082Lfs*4 | Frame Shift Del (DEL) | VAF 36/119 reads (30%) | called by mutect2, pindel, varscan2
- LAMC3 | c.4141G>A p.E1381K | Missense Mutation (SNP) | VAF 94/218 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.566); called by muse, mutect2, varscan2
- LRRC53 | c.2122dup p.L708Pfs*6 | Frame Shift Ins (INS) | VAF 58/154 reads (38%) | called by mutect2, pindel, varscan2
- PLAA | c.2124C>G p.N708K | Missense Mutation (SNP) | VAF 73/143 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PWWP2A | c.82G>A p.E28K | Missense Mutation (SNP) | VAF 29/63 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.187); called by muse, mutect2, varscan2
- RBAK | c.2036A>G p.Y679C | Missense Mutation (SNP) | VAF 58/175 reads (33%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- SLC17A5 | c.1096A>G p.I366V | Missense Mutation (SNP) | VAF 35/78 reads (45%) | SIFT tolerated (0.68); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SPEG | c.7219C>T p.R2407C | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ST7L | c.467G>A p.R156K | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.955); called by muse, varscan2
- SULT4A1 | c.298A>G p.K100E | Missense Mutation (SNP) | VAF 34/131 reads (26%) | SIFT tolerated (0.15); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- TRAF7 | c.547G>C p.E183Q | Missense Mutation (SNP) | VAF 11/103 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.231); called by muse, mutect2, varscan2
- VASH1 | c.728T>C p.F243S | Missense Mutation (SNP) | VAF 44/48 reads (92%) | SIFT deleterious (0); PolyPhen benign (0.246); called by muse, varscan2
- ZMYND11 | c.1306G>C p.V436L | Missense Mutation (SNP) | VAF 33/177 reads (19%) | SIFT tolerated (0.32); PolyPhen benign (0.268); called by muse, mutect2, varscan2
- ZNF679 | c.530G>A p.R177K | Missense Mutation (SNP) | VAF 57/182 reads (31%) | SIFT tolerated (0.16); PolyPhen benign (0.142); called by muse, mutect2, varscan2
- ABHD13 | c.645G>A p.V215= | Silent (SNP) | VAF 28/114 reads (25%) | called by muse, mutect2, varscan2
- ARHGAP44 | c.687C>T p.S229= | Silent (SNP) | VAF 19/39 reads (49%) | called by muse, mutect2, varscan2
- IGHV2-70 | c.282C>G p.T94= | Silent (SNP) | VAF 39/43 reads (91%) | catalogued as rs368464634; called by muse, mutect2, varscan2
- IGLL5 | c.115C>T p.L39= | Silent (SNP) | VAF 24/50 reads (48%) | catalogued as rs763474712, COSV73248991, COSV73251236, COSV73251304; called by muse, mutect2, varscan2
- LAMA5 | c.8430G>T p.L2810= | Silent (SNP) | VAF 67/137 reads (49%) | catalogued as rs1175850144; called by muse, mutect2, varscan2
- NPHP4 | c.4146G>C p.G1382= | Silent (SNP) | VAF 10/124 reads (8%) | catalogued as rs1159871433; called by muse, mutect2
- OGDH | c.2217C>T p.A739= | Silent (SNP) | VAF 8/72 reads (11%) | called by muse, mutect2, varscan2
- OR4C6 | c.861G>A p.L287= | Silent (SNP) | VAF 15/288 reads (5%) | catalogued as COSV58605815; called by muse, mutect2
- RAB3GAP2 | c.3573C>T p.F1191= | Silent (SNP) | VAF 18/39 reads (46%) | catalogued as COSV62785809; called by muse, mutect2, varscan2
- RP1L1 | c.1974A>G p.R658= | Silent (SNP) | VAF 37/100 reads (37%) | called by muse, mutect2, varscan2
- AC105001.2 | c.-19G>A | 5'UTR (SNP) | VAF 80/178 reads (45%) | catalogued as rs761666883; called by muse, mutect2
- ADAM17 | c.*792A>C | 3'UTR (SNP) | VAF 6/13 reads (46%) | called by muse, mutect2, varscan2
- ADAP2 | c.*403C>G | 3'UTR (SNP) | VAF 30/84 reads (36%) | called by muse, mutect2, varscan2
- ANKMY1 | c.1565+737C>A | Intron (SNP) | VAF 60/137 reads (44%) | called by muse, mutect2, varscan2
- ANKMY2 | c.*361G>C | 3'UTR (SNP) | VAF 32/162 reads (20%) | called by muse, mutect2, varscan2
- ARID4A | c.*565G>A | 3'UTR (SNP) | VAF 7/89 reads (8%) | catalogued as COSV100794640; called by muse, mutect2
- ARID5B | c.*1227A>G | 3'UTR (SNP) | VAF 27/61 reads (44%) | catalogued as rs1395970321; called by muse, mutect2, varscan2
- ATF6 | c.*2814G>T | 3'UTR (SNP) | VAF 35/82 reads (43%) | called by muse, mutect2, varscan2
- BCL2 | c.*3167C>T | 3'UTR (SNP) | VAF 57/105 reads (54%) | called by muse, mutect2, varscan2
- BMF | c.*99dup | 3'UTR (INS) | VAF 55/121 reads (45%) | called by mutect2, varscan2
- C11orf1 | c.*25T>C | 3'UTR (SNP) | VAF 62/284 reads (22%) | called by muse, mutect2, varscan2
- CHRNA4 | c.*1217G>C | 3'UTR (SNP) | VAF 37/84 reads (44%) | called by muse, mutect2, varscan2
- CRIM1 | c.332-18022G>A | Intron (SNP) | VAF 21/56 reads (38%) | called by muse, mutect2, varscan2
- CRYZL1 | c.904+497G>A | Intron (SNP) | VAF 25/63 reads (40%) | called by muse, mutect2, varscan2
- CTSC | c.318+6731C>T | Intron (SNP) | VAF 52/112 reads (46%) | catalogued as rs752407638; called by muse, mutect2, varscan2
- CXCR6 | c.*326G>C | 3'UTR (SNP) | VAF 4/34 reads (12%) | called by muse, mutect2
- DBF4 | chr7:87876468 C>T | 5'Flank (SNP) | VAF 11/27 reads (41%) | called by muse, mutect2, varscan2
- DBF4 | chr7:87876469 G>T | 5'Flank (SNP) | VAF 10/26 reads (38%) | called by muse, mutect2, varscan2
- DHRS7B | c.-39C>T | 5'UTR (SNP) | VAF 50/113 reads (44%) | catalogued as rs764853081; called by muse, mutect2, varscan2
- DTX3L | c.*1626G>A | 3'UTR (SNP) | VAF 3/45 reads (7%) | called by muse, mutect2
- ERICH1 | c.1258+786G>A | Intron (SNP) | VAF 63/156 reads (40%) | catalogued as rs542208788; called by muse, mutect2, varscan2
- F11 | c.485+139T>A | Intron (SNP) | VAF 27/78 reads (35%) | called by muse, mutect2, varscan2
- FAIM2 | c.*622C>T | 3'UTR (SNP) | VAF 96/215 reads (45%) | called by muse, mutect2, varscan2
- FGD3 | c.*609G>A | 3'UTR (SNP) | VAF 35/62 reads (56%) | called by muse, mutect2, varscan2
- FMNL3 | c.*3323G>C | 3'UTR (SNP) | VAF 31/61 reads (51%) | called by muse, mutect2, varscan2
- GABRG2 | c.-66T>G | 5'UTR (SNP) | VAF 138/260 reads (53%) | called by muse, mutect2, varscan2
- GLCCI1 | c.*214C>T | 3'UTR (SNP) | VAF 40/124 reads (32%) | called by muse, mutect2, varscan2
- GNPTG | c.53-12C>T | Intron (SNP) | VAF 15/26 reads (58%) | called by muse, mutect2, varscan2
- GPAT4 | c.*898C>T | 3'UTR (SNP) | VAF 38/71 reads (54%) | called by muse, mutect2, varscan2
- IYD | c.688-1798G>T | Intron (SNP) | VAF 8/92 reads (9%) | called by muse, mutect2
- KLHL9 | c.*975G>T | 3'UTR (SNP) | VAF 29/76 reads (38%) | called by muse, mutect2, varscan2
- LONRF2 | c.*10580A>C | 3'UTR (SNP) | VAF 59/113 reads (52%) | called by muse, mutect2, varscan2
- MAP4K4 | chr2:101891739 T>G | 3'Flank (SNP) | VAF 17/48 reads (35%) | called by muse, mutect2, varscan2
- MLLT10 | c.240+18261T>C | Intron (SNP) | VAF 27/78 reads (35%) | catalogued as rs1015456299; called by muse, mutect2, varscan2
- MSL3 | c.*319C>A | 3'UTR (SNP) | VAF 20/20 reads (100%) | called by muse, mutect2, varscan2
- MYCBP2 | c.8027-149del | Intron (DEL) | VAF 14/41 reads (34%) | catalogued as rs1379398533; called by mutect2, pindel, varscan2
- MYO16 | c.-39+33541G>A | Intron (SNP) | VAF 78/179 reads (44%) | catalogued as COSV100762972; called by muse, mutect2, varscan2
- NFIB | c.*730G>T | 3'UTR (SNP) | VAF 6/22 reads (27%) | called by muse, mutect2, varscan2
- NOS1 | c.*2507A>G | 3'UTR (SNP) | VAF 65/71 reads (92%) | called by muse, mutect2, varscan2
- NPY2R | c.*498G>T | 3'UTR (SNP) | VAF 18/35 reads (51%) | called by muse, mutect2, varscan2
- OR4A4P | n.501T>C | RNA (SNP) | VAF 63/129 reads (49%) | called by muse, mutect2, varscan2
- PAQR5 | c.*129T>C | 3'UTR (SNP) | VAF 28/53 reads (53%) | called by muse, mutect2, varscan2
- PAX3 | chr2:222200556 T>C | 3'Flank (SNP) | VAF 29/76 reads (38%) | called by muse, mutect2, varscan2
- PHYH | chr10:13302058 G>A | 5'Flank (SNP) | VAF 51/104 reads (49%) | catalogued as rs1017656647; called by muse, mutect2, varscan2
- PIK3C2G | c.*299T>A | 3'UTR (SNP) | VAF 16/40 reads (40%) | called by muse, mutect2
- PIK3C2G | c.*301G>T | 3'UTR (SNP) | VAF 18/41 reads (44%) | called by muse, mutect2
- SFXN3 | c.881+67C>G | Intron (SNP) | VAF 43/95 reads (45%) | called by muse, mutect2, varscan2
- SIN3B | c.2956-63G>C | Intron (SNP) | VAF 8/138 reads (6%) | catalogued as rs898046747; called by muse, mutect2
- SLC35B1 | c.*353G>A | 3'UTR (SNP) | VAF 14/125 reads (11%) | catalogued as rs949036159; called by muse, mutect2, varscan2
- SORBS2 | c.3134+13_3134+15del | Intron (DEL) | VAF 56/148 reads (38%) | catalogued as rs748822434; called by pindel, varscan2
- SSBP2 | c.*4277del | 3'UTR (DEL) | VAF 16/45 reads (36%) | catalogued as rs542910002; called by mutect2, varscan2
- THSD7B | c.*326C>G | 3'UTR (SNP) | VAF 17/49 reads (35%) | called by muse, mutect2, varscan2
- TMEM201 | c.1160+641T>C | Intron (SNP) | VAF 16/113 reads (14%) | called by muse, mutect2, varscan2
- TRAPPC13 | c.*785C>T | 3'UTR (SNP) | VAF 8/70 reads (11%) | called by muse, mutect2, varscan2
- TRNAU1AP | chr1:28578786 del G | 3'Flank (DEL) | VAF 50/130 reads (38%) | called by mutect2, pindel, varscan2
- WFIKKN2 | c.*63C>G | 3'UTR (SNP) | VAF 11/26 reads (42%) | catalogued as COSV100260108; called by muse, mutect2, varscan2
- ZNF765 | c.*2626G>A | 3'UTR (SNP) | VAF 66/134 reads (49%) | called by muse, mutect2, varscan2
